CCDI case PBCHUV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/22a34653-dae5-4a9f-9252-da5951f10366

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Papillary carcinoma, NOS: ICD-O-3 morphology code: 8050/3; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 5.7 years (2,067 days).

Biospecimens (3 samples)
- Sample 0DX2CB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DX2CU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DX2CY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
